Somatic mutation profile of tumor specimen C3L-07959-05 (aliquot CPT0451430006) from CPTAC case C3L-07959, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 49.5 years (18,089 days).
Specimen C3L-07959-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1dc4c64-6729-4586-895f-ae51729a67be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07959-31 (Blood Derived Normal), aliquot CPT0451540004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cdf3e90-7b86-4b48-9339-c621280f9929

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, Nonsense Mutation 4, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSAG1 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 16/492 reads (3%) | catalogued as COSV63400012; called by muse, mutect2
- ERBB3 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 20/369 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV57246873; called by muse, mutect2
- EYS | c.855A>C p.Q285H | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100676928, COSV60977652; called by muse, mutect2
- FAT2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs978707253, COSV55833888; called by muse, mutect2
- GAD2 | c.1496C>G p.P499R | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52168645; called by muse, mutect2
- GP9 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 40/576 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752262357; called by muse, mutect2
- HNRNPM | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 32/724 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs778586401; called by muse, mutect2
- KLHL26 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 35/545 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.166); catalogued as rs1325421378; called by muse, mutect2
- NLGN2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57209920; called by muse, mutect2
- PGLYRP2 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373319363; called by muse, mutect2
- PHOX2B | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV56931077; called by muse, mutect2
- PLG | c.1753T>G p.C585G | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100368823; called by muse, mutect2
- PLXNA3 | c.2683G>A p.V895M | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782287371, COSV100860374; called by muse, mutect2
- SP8 | c.938C>T p.A313V (on ENST00000361443 / NM_198956.4; = p.A331V on NM_182700.6) | Missense Mutation (SNP) | VAF 42/528 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs1167135932; called by muse, mutect2
- SRCAP | c.2682G>C p.L894F | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52683033; called by muse, mutect2
- STARD8 | c.2734G>A p.D912N | Missense Mutation (SNP) | VAF 46/490 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs762679306, COSV99367573; called by muse, mutect2
- UNC80 | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 26/519 reads (5%) | catalogued as rs1035839091; called by muse, mutect2
- ZNF831 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 50/444 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs974634688, COSV100926207; called by muse, mutect2, varscan2
- ARMC10 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 24/548 reads (4%) | called by muse, mutect2
- B3GNT6 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 15/519 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); called by muse, mutect2
- DCC | c.2894T>G p.V965G | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FAM135A | c.775T>G p.F259V (on ENST00000370479 / NM_001351599.1; = p.F216V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- FGD5 | c.2362C>T p.Q788* | Nonsense Mutation (SNP) | VAF 21/331 reads (6%) | called by muse, mutect2
- HELZ | c.3434G>A p.G1145E | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR2I1P | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2
- PHF8 | c.2557C>T p.P853S (on ENST00000357988 / NM_001184896.1; = p.P817S on NM_015107.3) | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- RYR2 | c.9709G>T p.V3237F | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- TBX1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- TLN2 | c.7053A>T p.K2351N | Missense Mutation (SNP) | VAF 15/383 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIB1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 30/461 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- TRIM58 | c.1342T>C p.F448L | Missense Mutation (SNP) | VAF 18/425 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- AC100868.1 | c.1182C>G p.T394= | Silent (SNP) | VAF 19/306 reads (6%) | catalogued as COSV51844071; called by muse, mutect2
- C8A | c.1293C>T p.S431= | Silent (SNP) | VAF 32/408 reads (8%) | catalogued as rs757671432; called by muse, mutect2
- CLDN10 | c.165C>T p.T55= | Silent (SNP) | VAF 20/445 reads (4%) | catalogued as COSV54823149; called by muse, mutect2
- CSMD3 | c.7182G>T p.V2394= (on ENST00000297405 / NM_001363185.1; = p.V2290= on NM_052900.3) | Silent (SNP) | VAF 11/396 reads (3%) | called by muse, mutect2
- DRD2 | c.342C>T p.D114= | Silent (SNP) | VAF 19/310 reads (6%) | catalogued as rs200402411, COSV100670320, COSV60754615; called by muse, mutect2
- GRID1 | c.111C>T p.D37= | Silent (SNP) | VAF 23/371 reads (6%) | catalogued as rs1390185701; called by muse, mutect2
- HAS1 | c.753G>T p.V251= | Silent (SNP) | VAF 14/286 reads (5%) | catalogued as rs1433977319; called by muse, mutect2
- HMCN1 | c.16062C>T p.C5354= | Silent (SNP) | VAF 30/418 reads (7%) | catalogued as rs770321756; called by muse, mutect2
- MYOCD | c.492G>A p.P164= | Silent (SNP) | VAF 28/404 reads (7%) | catalogued as rs745617618, COSV58507592; called by muse, mutect2
- RIPOR3 | c.465C>T p.G155= | Silent (SNP) | VAF 32/518 reads (6%) | catalogued as rs751111641, COSV50387628; called by muse, mutect2
- SASH1 | c.1728G>A p.K576= | Silent (SNP) | VAF 24/312 reads (8%) | called by muse, mutect2
- ZNF423 | c.3702C>T p.G1234= (on ENST00000563137 / NM_001379286.1; = p.G1226= on NM_015069.4) | Silent (SNP) | VAF 28/378 reads (7%) | catalogued as rs766215720, COSV52198135; called by muse, mutect2
- MFRP | chr11:119344978 G>A | 5'Flank (SNP) | VAF 27/302 reads (9%) | catalogued as rs368844563; called by muse, mutect2
- ZNF578 | chr19:52451212 G>A | 5'Flank (SNP) | VAF 13/239 reads (5%) | called by muse, mutect2
